Surgical pathology report (de-identified scan), TCGA case TCGA-DC-6154, project TCGA-READ (Rectum Adenocarcinoma), tissue source site MSKCC, specimen TCGA-DC-6154-01A (Primary Tumor).

[page 1 of 5]
[REDACTED]

SURGICAL PATHOLOGY REPORT

[REDACTED]

....

Clinical Diagnosis & History:
Metastatic colon cancer.

Specimens Submitted:
1: SP: Segment 2 and 3 of liver
2: SP: Large bowel, rectosigmoid, low anterior resection
3: SP: Proximal ring
4: SP: Distal ring
5: SP: Right fallopian and ovary
6: SP: Left fallopian and ovary

DIAGNOSIS:

1. LIVER, SEGMENTS II AND III; RESECTION:
-METASTATIC MODERATELY-DIFFERENTIATED COLONIC ADENOCARCINOMA, 3.4 CM,
SHOWING 20% NECROSIS.
-THE CARCINOMA IS 0.5 CM FROM THE MARGIN OF RESECTION
- THE NON-NEOPLASTIC LIVER IS UNREMARKABLE.
2. SP: Large bowel, rectosigmoid, low anterior resection:
Tumor Type:
Adenocarcinoma
Histologic Grade:
Moderately differentiated
Tumor Location:
Rectosigmoid
Tumor Size:
Length is 5.8 cm
Width is 3.5 cm
Maximal thickness is 1.2 cm
Tumor Budding:
Absent
Increased Tumor Infiltrating Lymphocytes:
Absent
Precursor Lesions:
Not identified
Deepest Tumor Invasion:
Serosal surface
Gross Tumor Perforation:
Suspected based on microscopic findings

** Continued on next page **

[page 2 of 5]
Lymphovascular Invasion:
Identified
Large Venous Invasion:
Identified
Perineural Invasion:
Identified
Surgical Margins:
Free of tumor
Polyps/Mucosa Dysplasia (away from the carcinoma):
Not Identified
Non-Neoplastic Bowel:
Unremarkable
Lymph Nodes:
Number with metastasis: 8
Total number examined: 39
Tumor deposits in pericorectal soft tissue:
Not Identified
Tumor Staging (AJCC 7th Edition):
pT4a (Tumor penetrates to the surface of the visceral peritoneum)
Lymph Node Stage (AJCC 7th Edition):
N2b (Metastasis in seven or more regional lymph nodes)

3. COLON, SIGMOID, PROXIMAL RING; RESECTION
-SEGMENT OF COLON WITH NO PATHOLOGIC DIAGNOSIS, NEGATIVE FOR CARCINOMA
4. RECTUM, DISTAL RING; RESECTION
-SEGMENT OF RECTUM WITH NO PATHOLOGIC DIAGNOSIS, NEGATIVE FOR CARCINOMA
5. OVARY AND FALLOPIAN TUBE, RIGHT; RESECTION
-FALLOPIAN TUBE WITH BENIGN PARATUBAL CYSTS
-OVARY WITH NO PATHOLOGIC DIAGNOSIS
6. OVARY AND FALLOPIAN TUBE, LEFT; RESECTION
-FALLOPIAN TUBE AND OVARY WITH NO PATHOLOGIC DIAGNOSIS

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

1) The specimen is received fresh and labeled, "segment 2 and 3 of liver*". It consists of a liver lobe measuring 12x5.6x3.1 cm. The hepatic capsule is grossly intact and is inked black. There is a rough hepatic resection margin which is inked blue. Serial sectioning at 0.5 cm intervals reveals tan-yellow, relatively well-circumscribed firm mass measuring 3.4x3.1x2.7 cm. There is no gross evidence of tumor within the vessels. There is no

** Continued on next page **

[page 3 of 5]
gross evidence of tumor within the bile ducts. The tumor is 0.6 cm from the inked surgical resection margin. The remaining hepatic parenchyma is unremarkable. Representative sections are submitted. Portion of the tumor is submitted for [REDACTED]

Summary of sections:

TC - tumor with hepatic capsule

TM - tumor with margin

U - uninvolved hepatic parenchyma (away from the mass)

[REDACTED]

2). The specimen is received fresh and is labeled "Low anterior resection colon". It consists of a rectosigmoid colon that measures 18.0 x 6.3 cm at the distal margin. The serosal surface has an area of central retraction and narrowing. The affected serosa is inked blue the radial resection margin is inked black and the specimen is opened to reveal a circumferential ulcerated tumor with heaped up borders that is located 5.7 cm from the proximal margin and 6.5 cm from the distal margin. The tumor measures 5.8 cm in length and 3.5 cm in width. Serial sectioning reveals tumor invasion to a depth of 1.2cm grossly extending through the muscularis into the pericolic fat, 1.8cm from the radial margin but grossly abutting the retracted serosa. There is an underlying grossly positive lymph node which is 1.2 cm from the radial margin, which is submitted and an additional grossly positive lymph node which is abutting the radial margin. The muscularis proximal to the tumor is thickened up to 0.6cm. The remaining mucosa shows no other discrete lesions and is otherwise unremarkable. Pericolic and peri-rectal adipose tissue is thoroughly examined for lymph nodes and three grossly positive lymph nodes are partially submitted for TPS, the remaining lymph nodes are submitted accordingly. Representative sections are submitted. [REDACTED] is submitted.

Summary of sections:

PM - proximal margin

DM - distal margin

RM - radial margin

T tumor

TLN1 tumor with underlying positive lymph node 1 [REDACTED]

LN2 - grossly positive lymph node 2 [REDACTED]

LN3-grossly positive lymph node 3 [REDACTED]

LN4 grossly positive lymph node 4 (with radial margin)

RS- uninvolved mucosa

LN - lymph nodes

BLN - bisected lymph node

[REDACTED]

3) The specimen is received in formalin, labeled "proximal ring" and consists of a segment of unremarkable intestine, measuring 2 cm in diameter and 0.5 cm in thickness. Entirely submitted.

Summary of sections:

U-undesignated

[REDACTED]

** Continued on next page **

[page 4 of 5]
4) The specimen is received in formalin, labeled "distal ring" and consists of a segment of unremarkable intestine, measuring 1.8 cm in diameter and 0.4 cm in thickness. Entirely submitted.

Summary of sections:
U-undesignated

5) The specimen is received in formalin, labeled "left tube and ovary" and consists of a fallopian tube with attached ovary. The fallopian tube measures 4.5 cm in length and averages 0.5 cm in diameter. The external surface of the tube is pink tan and smooth with a normal fimbriated end. Cut section through the tube reveals a pinpoint lumen. The attached ovary measures 2.2x1.2x0.5 Cm. The external surface is unremarkable. Cut section through the ovary is unremarkable. Ovary is entirely submitted; and fallopian tube is representatively submitted.

Summary of sections:
F - fallopian tube
O - ovary

6) The specimen is received in formalin, labeled "right tube and ovary" and consists of a fallopian tube with attached ovary. The fallopian tube measures 4.7 cm in length and averages 0.7 cm in diameter. The external surface of the tube is pink tan and smooth with a normal fimbriated end. Cut section through the tube reveals a pinpoint lumen. The attached ovary measures 1.6x1.2x0.5 Cm. The external surface is unremarkable. Cut section through the ovary is unremarkable. Ovary is entirely submitted; and fallopian tube is representatively submitted.

Summary of sections:
F - fallopian tube
O - ovary

Summary of Sections:
Part 1: SP: Segment 2 and 3 of liver

Block	Sect.	Site	PCs
2		tm	2
3		tp	3
1		u	1

Part 2: SP: Large bowel, rectosigmoid, low anterior resection

** Continued on next page **

[page 5 of 5]
Block	Sect.	Site	PCs
2		DM	2
8		LN	22
1		LN2	1
1		LN3	1
1		LN4	1
2		PM	2
1		RM	1
2		RS	2
4		T	4
1		TLN1	1

Part 3: SP: Proximal ring

Block	Sect.	Site	PCs
1		u	1

Part 4: SP: Distal ring

Block	Sect.	Site	PCs
1		u	1

Part 5: SP: Right fallopian and ovary

Block	Sect.	Site	PCs
1		ft	1
2		o	2

Part 6: SP: Left fallopian and ovary

Block	Sect.	Site	PCs
1		ft	1
2		o	2

Source: NCI Genomic Data Commons file af6e04fa-9a56-410c-9357-c25d07caeb96 (TCGA-DC-6154.90BFA167-284C-4B36-B47E-52A5DC58ECCD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).